FM case AD10974 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Germ Cell Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/7bc0161a-2589-417e-acd0-1e502c21d372

Female, 53.2 years: Germ cell tumor, NOS (ICD-O-3 9064/3) of the ovary; metastasis biopsied or resected from the uterus. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
